Somatic mutation profile of tumor specimen TCGA-AB-2847-03B (aliquot TCGA-AB-2847-03B-01W-0728-08) from TCGA case TCGA-AB-2847, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.3 years (19,481 days).
Specimen TCGA-AB-2847-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2c9852a-4b93-418e-9a30-d44b15782108.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2847-11B (Solid Tissue Normal), aliquot TCGA-AB-2847-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10586c01-40eb-4df5-a5c1-2c72bd43567b

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2A | c.740G>A p.G247D (on ENST00000219054; = p.G168D on NM_001308169.2) | Missense Mutation (SNP) | VAF 96/350 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.105); catalogued as COSV54583314; called by muse, mutect2, varscan2
- ADAMTS16 | c.2309G>A p.G770E | Missense Mutation (SNP) | VAF 172/410 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56982813, COSV56997422; called by muse, varscan2
- OR2AG1 | c.392C>A p.T131K | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs769923862, COSV56625685; called by muse, mutect2, varscan2
- TECRL | c.221G>A p.C74Y | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs894970499, COSV101169289; called by muse, varscan2
- USP6 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.097); catalogued as COSV100004736; called by muse, mutect2
- LRP1B | c.5856G>A p.L1952= | Silent (SNP) | VAF 68/247 reads (28%) | catalogued as COSV67198964; called by muse, mutect2, varscan2
- PDZD8 | c.1923C>T p.A641= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV100559615; called by muse, mutect2
